Surgical pathology report (de-identified scan), TCGA case TCGA-IN-A6RL, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-A6RL-01A (Primary Tumor).

[page 1 of 3]
FINAL DIAGNOSIS:

- PART 1: LYMPH NODE, LEVEL 7 NEAR BRONCHUS INTERMEDIUS, BIOPSY -
NO TUMOR PRESENT IN ONE LYMPH NODE (0/1).
- PART 2: LYMPH NODE, LEVEL 7 NEAR CARINA, BIOPSY -
NO TUMOR PRESENT IN ONE LYMPH NODE (0/1).
- PART 3: LYMPH NODE, LEVEL 7 NEAR LEFT MAIN BRONCHUS, BIOPSY -
NO TUMOR PRESENT IN ONE LYMPH NODE (0/1).
- PART 4: LYMPH NODE, PERIESOPHAGEAL, BIOPSY -
A. BENIGN FIBROADIPOSE TISSUE.
B. NO LYMPH NODE IDENTIFIED.
- PART 5: SOFT TISSUE, PERIESOPHAGEAL -
A. BENIGN FIBROADIPOSE TISSUE.
B. NO TUMOR PRESENT.
- PART 6: ESOPHAGUS, ESOPHAGECTOMY -
A. MODERATELY DIFFERENTIATED ADENOCARCINOMA, 3.5 CM, INVASIVE INTO BUT NOT THROUGH THE MUSCULARIS PROPRIA, LOCATED AT THE GASTROESOPHAGEAL JUNCTION.
B. ANGIOLYMPHATIC AND PERINEURAL INVASION PRESENT.
C. MARGINS FREE OF TUMOR; TUMOR IS 0.1 CM FROM THE CIRCUMFERENTIAL (ADVENTITIAL) MARGIN.
D. PATHOLOGIC STAGE: pT2 pN2.
E. ADDITIONAL FINDINGS:
a. HIGH-GRADE COLUMNAR EPITHELIAL DYSPLASIA ASSOCIATED WITH THE INVASIVE ADENOCARCINOMA.
b. NO DEFINITIVE BARRETT'S MUCOSA IDENTIFIED.
F. GASTRIC MUCOSA OTHERWISE WITHOUT SIGNIFICANT ABNORMALITY.
- PART 7: ANASTOMOTIC RINGS, RESECTION -
NO TUMOR PRESENT.
- PART 8: FINAL GASTRIC MARGIN, RESECTION -
NO TUMOR PRESENT.
- PART 9: GASTROESOPHAGEAL FAT, RESECTION -
A. METASTATIC ADENOCARCINOMA IN THREE OF EIGHTEEN LYMPH NODES (3/18).
B. NON-NECROTIZING FIBROTIC GRANULOMAS INVOLVING ONE ANTHRACOTIC LYMPH NODE.
C. RESULTS OF GROCOTT AND AFB STAINS WILL BE REPORTED IN AN ADDENDUM.
- PART 10: LYMPH NODE, SUBCARINAL NEAR AZYGOUS, BIOPSY -
NO TUMOR PRESENT IN ONE LYMPH NODE (0/1).
- PART 11: LYMPH NODE, PERIGASTRIC, BIOPSY -
METASTATIC ADENOCARCINOMA IN ONE OF ONE LYMPH NODE (1/1).
- PART 12: LYMPH NODE, LEVEL 7, BIOPSY -
NO TUMOR PRESENT IN ONE LYMPH NODE (0/1).
- PART 13: LYMPH NODE, SUBCARINAL "ON ESOPHAGUS", BIOPSY -
NO TUMOR PRESENT IN ONE LYMPH NODE (0).
- PART 14: LYMPH NODE, SUBCARINAL, BIOPSY -
NO TUMOR PRESENT IN ONE LYMPH NODE (0/1).
- PART 15: LYMPH NODE, NEAR GASTRIC CURVE, BIOPSY -
METASTATIC ADENOCARCINOMA IN ONE OF ONE LYMPH NODE (1/1) WITH EXTRACAPSULAR EXTENSION.
- PART 16: LYMPH NODE, GASTRIC FAT, BIOPSY -
NO TUMOR PRESENT IN ONE LYMPH NODE (0/1).
- PART 17: LYMPH NODE, FAT PAD, BIOPSY -
NO TUMOR PRESENT IN ONE LYMPH NODE (0/1).

Collection Date:

1CD-0-3

adenocarcinoma, NOS 8140/3
Site: gastroesophageal junction 46.0

hw/2/13

[page 2 of 3]
COMPREHENSIVE THERANOSTIC SUMMARY

IMMUNOHISTOCHEMISTRY:
Her2:

RESULTS
EQUIVOCAL (2+)

IN SITU HYBRIDIZATION / FISH:
HER2 (ERBB2) amplification:

RESULTS
NEGATIVE

Addendum

Part 9: Grocott and AFB stains are negative for fungal and mycobacterial organisms.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS

----- MACROSCOPIC -----

SPECIMEN TYPE: Esophagectomy
TUMOR SITE: Tumor midpoint centered on esophagogastric junction
TUMOR SIZE: Greatest dimension: 3.5 cm
Additional dimensions: 2.0, 1.0 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G2
PATHOLOGIC STAGING (pTNM)

pT2
pN2
Number of lymph nodes examined: 29
Number of lymph nodes involved: 5
pM Not applicable
No prior treatment

PRIOR TREATMENT:
MARGINS

Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (adventitial) margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 1 mm
Specify margin: Circumferential

ANGIOLYMPHATIC INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS:

High grade dysplasia

[page 3 of 3]
SPECIAL PROCEDURES:

In Situ Procedure

Interpretation

HER2 FISH STUDIES PERFORMED ON THE ADENOCARCINOMA ARE NEGATIVE.

Cells Analyzed: 63

Ratio HER2/CEP17: 1.28

SNR: 2.9

CNR: 2.2

% Hyperdiploid: 21(33.3%)

HER2 IMMUNOPEROXIDASE STUDIES PERFORMED ON THE ADENOCARCINOMA ARE EQUIVOCAL

IHC score: 2+.

Results

INTERPRETATION GUIDELINES AND PROBE/CLONE INFORMATION:

FISH:

Probe: HER2 DNA Probe

Probe Description: The HER2 DNA probe is a 190 Kb directly labeled fluorescent DNA probe specific for the HER2 gene locus. The CEP 17 DNA probe is a 5.4 Kb directly labeled fluorescent DNA probe specific for the alpha satellite DNA sequence at the centromeric region of chromosome 17. The probes are pre-mixed and pre-denatured in hybridization buffer.

Interpretation:

HER2 negative: HER2 gene/chromosome 17 ratio less than 2.0

HER2 positive: HER2 gene/chromosome 17 ratio greater than 2.0

Results should be considered along with other clinical information.

The modifications have been tested and validated. The modifications are as follows: Slides are deparaffinized in Tissue is digested in protease 31 minutes; Tissue and probe are co-denatured at 90 C for 12 minutes; Paraffin pretreatment reagents and control slides are prepared in house. Amplified, non-amplified, and internal (centromere 17) controls were used in the testing. The laboratory takes responsibility for the test performance.

FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the HER2 and the CEP17 probes.

IHC:

anti-HER-2/neu (4B5) Rabbit Monoclonal Primary Antibody

Tumors are considered POSITIVE if they show HER2 protein over-expression (3+) by IHC.

IHC scoring for HER2 in gastric and GE junction cancer by type of diagnostic specimen:

SCORE SURGICAL SPECIMEN-STAINING PATTERN

NEGATIVE

0 No reactivity or membranous reactivity in <10% of tumor cells

1+ Faint/barely perceptible membranous reactivity in $\geq 10\%$ of tumor cells; cells are reactive only in part of their membrane

EQUIVOCAL

2+ Weak to moderate complete, basolateral or lateral membranous reactivity in $\geq 10\%$ of tumor cells

POSITIVE

3+ Strong complete, basolateral or lateral membranous reactivity in $\geq 10\%$ of tumor cells

BIOPSY SPECIMEN-STAINING PATTERN

NEGATIVE

0 No reactivity or no membranous reactivity in any (or <5 clustered) tumor cells

1+ Tumor cell cluster (≥ 5 cells) with a faint/barely perceptible membranous reactivity irrespective of percentage of tumor cells stained

EQUIVOCAL

2+ Tumor cell cluster (≥ 5 cells) with a weak to moderate complete, basolateral or lateral membranous reactivity irrespective of percentage of tumor cells stained

POSITIVE

3+ Tumor cell cluster (≥ 5 cells) with a strong complete, basolateral or lateral membranous reactivity irrespective of percentage of tumor cells stained

Source: NCI Genomic Data Commons file 170e73d6-73eb-4563-b26b-83993e6df625 (TCGA-IN-A6RL.BBD38294-0174-48C8-8A3F-2B5FABC536A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).